Somatic mutation profile of tumor specimen ALCH-AENG-TTP1-A (aliquot ALCH-AENG-TTP1-A-1-0-D-A612-36) from ALCHEMIST case ALCH-AENG, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 69.4 years (25,349 days).
Specimen ALCH-AENG-TTP1-A: Sample type: FFPE Scrolls; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) da6027d2-4559-4a90-accb-231ffaffe6f0.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-AENG-NB1-A (Blood Derived Normal), aliquot ALCH-AENG-NB1-A-1-0-D-A612-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/eb13e5b3-9a8a-4285-a734-65ef9c0aeab7

The open-access MAF lists 2 somatic variants for this specimen: 1 protein-altering or splice-affecting, 1 silent.
By variant classification: Splice Site 1, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- WWP1 | c.540-4_543delinsTTTTTTTT p.X180_splice | Splice Site (ONP) | VAF 10/118 reads (8%) | called by mutect2*, pindel
- IQSEC3 | c.3135T>G p.L1045= | Silent (SNP) | VAF 3/14 reads (21%) | called by muse, mutect2
